Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-A4C6, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-A4C6-01A (Primary Tumor).

[page 1 of 6]
Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: M

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location:

Facility:

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Salivary-Gland: RIGHT PAROTID DUCT. QUICK SECTION.
2. Soft Tissue: Right buccal tumor double short 12 o'clock ,double long 3 o'clock, single long 9 o'clock, blue stitch 6 o'clock
3. Soft Tissue: Right anterior mucosa margin
4. Soft Tissue: Right superior mucosae margin
5. Soft Tissue: Right inferior mucosae margin
6. Soft Tissue: Deep margin
7. Soft Tissue: Right portion mucosae margin
8. Soft Tissue: Right neck level 2B
9. Soft Tissue: Cotents right neck

ICD-0-3

carcinoma, squamous cell, NOS
8070/3

DIAGNOSIS

1. Right parotid duct:
- Soft tissue, negative for malignancy.
2. Right buccal; resection:
- Squamous cell carcinoma, moderately differentiated.
- a. Tumour maximum dimension 2.5 cm.
- b. Tumour maximum thickness 0.7 cm.
- c. Perineural invasion is present.
- d. No lymphovascular invasion identified.
- e. All margins, negative for malignancy (= 0.5 cm).
3. Right anterior mucosa margin:
- Squamous mucosa, negative for malignancy.
4. Right superior mucosa margin:
- Squamous mucosa, negative for malignancy.
5. Right inferior mucosa margin:
- Squamous mucosa, negative for malignancy.

Site: buccal mucosa C06.0

W 9/26/12

[page 2 of 6]
6. Deep margin:

Status: complete

Page: 1 of 5

Patient Name:	[REDACTED]	Service: Otolaryngology	Copath #:	[REDACTED]
MRN:	[REDACTED]	Visit #:	Collected:	[REDACTED]
DOB:	[REDACTED]	Location:	Resulted:	[REDACTED]
Gender:	[REDACTED]	Facility:		
Ordering MD:	[REDACTED]			

- Skeletal muscle, negative for malignancy.

7. Right posterior mucosa margin:

- Squamous mucosa, negative for malignancy.

8. Right neck, level IIB:

- Two lymph nodes, negative for malignancy (0/2).

9. Right neck contents:

- Twenty-one lymph nodes, negative for malignancy (0/21).

- Submandibular gland, negative for malignancy.

SYNOPTIC DATA

Specimen Type:	Resection:right buccal cavity
Tumor Site:	Oral Cavity
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 2.5 cm Tumor thickness: 0.7 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Present
Margins:	Margins uninvolved by tumor
Pathologic Staging (pTNM):	pT2: Tumor of lip or oral cavity
more than 2 cm but not more than 4 cm in greatest dimension	pN0: No regional lymph node
metastasis for aerodigestive sites	
examined: 23	Number of regional lymph nodes
involved: 0	Number of regional lymph nodes

[page 3 of 6]
assessed

PMX: Distant metastasis cannot be

*Pathologic Staging is based on AJCC/UICC TNM, 6th Edition

Status: complete

Page: 2 of 5

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location: [REDACTED]	Resulted: [REDACTED]
Gender: [REDACTED]	Facility: [REDACTED]	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

1. The specimen container labeled with the patient's name and as "Right Parotid Quick Section", contains a piece of tissue measuring 0.5 x 0.4 x 0.4 cm. received in 10% buffered formalin.

1A submitted in toto

2. The specimen labeled with the patient's name and as "Right Buccal Tumour Double Short, 12 O'clock, Double Long 3 o'clock Single Long 9 o'clock Blue Stitch 6 o'clock" consists of a piece of buccal mucosa, oriented with 4 sutures. The specimen measures 4.0 cm in 12-6 o'clock dimensions x 4.1 cm in 3-9 o'clock dimension x 1.4 cm in thickness. There is an elevated ulcerated brown lesion measuring 2.5 cm 12-6 o'clock x 2.4 cm 3-9 o'clock x 0.7 cm depth and is located 0.6 cm from the 12 o'clock margin, 1.1 from the 3 o'clock margin, 0.8 cm from the 6 o'clock margin, 1.2 cm from the 9 o'clock margin and 1.0-cm from the deep margin. The surgical margins are painted with silver nitrate. Two pieces of tumor and normal tissue is stored frozen. Representative sections are submitted as follows:

2A deep margin taken at frozen section

2B tumor with 12 o'clock margin

2C tumor with 3 o'clock margin

2D tumor with 6 o'clock margin

2E tumor with 9 o'clock margin

[page 4 of 6]
2F tumor with deep margin

3. The specimen container labeled with the patient' s name and as "RT Anterior Mucosal Margin", contains a piece of tissue measuring 1.0 x 0.5 x 0.4 cm. received in 10% buffered formalin.
3A submitted in toto,

4. The specimen container labeled with the patient' s name and as "RT Superior Mucosal Margin ", contains a piece of tissue measuring 1.3 x 0.4 x 0.4 cm. received in 10% buffered formalin.
4A submitted in toto,

5. The specimen container labeled with the patient' s name and as "RT

Status: complete

Page: 3 of 5

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location:	Resulted: [REDACTED]
Gender: [REDACTED]	Facility:	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

Inferior Mucosal Margin", contains a piece of tissue measuring 1.3 x 0.2 x 0.2 cm. received in 10% buffered formalin.
5A submitted in toto

6. The specimen container labeled with the patient' s name and as "Deep Margin ", contains a piece of tissue measuring 0.5 x 0.4 x 0.3 cm. received in 10% buffered formalin.
6A submitted in toto

7. The specimen container labeled with the patient' s name and as "RT Posterior Mucosal Margin", contains a piece of tissue measuring 1.1 x 0.1 x 0.1 cm. received in 10% buffered formalin.
7A submitted in toto

8. The specimen labeled with the patient's name and as "RT Neck Labeled 2B." consists of a piece of fibroadipose tissue that measures 1.5 x 1.5 x 0.5 cm.
8A submitted in toto

9. The specimen labeled with the patient's name and as "Contents RT Neck" consists of a standard right neck dissection received orientated on a green towel with overall dimensions of 10.4 x 7.2 x 2.0 cm. The internal

[page 5 of 6]
jugular vein is not grossly identified. The sternocleidomastoid is unremarkable and measures 3.0 x 2.9 x 0.9 cm. The submandibular gland measures 4.3 x 2.8 x 1.7 cm and is unremarkable. Multiple lymph nodes ranging from 0.4 to 1.4 cm are identified in multiple levels. Representative sections are submitted.

Level 1A

9A query one lymph node

9B submandibular gland

Level 1B

9C submandibular gland

9D query lymph node trisected

9E query two lymph nodes

Level 2A

9F 2 lymph nodes

9G 1 lymph node bisected

9H 1 lymph node bisected

Level 2B

9I two lymph nodes

Level 3

Status: complete

Page: 4 of 5

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

9J one lymph node

Level 4

9K one lymph node bisected

9L-9N multiple lymph nodes

9O one lymph node bisected

9P query one lymph node bisected

QUICK SECTION

1. Right parotid duct: Negative for malignancy.

2. Right buccal resection (deep margin for : Negative for malignancy.

3-7: Margins (right anterior mucosal, right superior mucosal, right inferior mucosal, deep and right posterior mucosal):

[page 6 of 6]
- Negative for malignancy.

Called at

Status: complete

Page: 5 of 5

Source: NCI Genomic Data Commons file 331bf7e0-9b73-4f27-91e2-01076fa3b0b3 (TCGA-CQ-A4C6.D025CC0C-B236-4166-995F-5D16B4AA4447.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).